Somatic mutation profile of tumor specimen C3N-02945-01 (aliquot CPT0158950009) from CPTAC case C3N-02945, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G4; Age at diagnosis: 66.2 years (24,182 days).
Specimen C3N-02945-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2c90b574-b2a3-492d-a61d-897e01d76997.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02945-32 (Blood Derived Normal), aliquot CPT0159450002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/651fd277-4569-4d5f-8b62-571613893f8c

The open-access MAF lists 54 somatic variants for this specimen: 34 protein-altering or splice-affecting, 14 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 14, 5'UTR 2, Frame Shift Ins 2, 5'Flank 2, Nonsense Mutation 2, In Frame Del 1, Splice Site 1, Frame Shift Del 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NADSYN1 | c.145T>C p.C49R | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.553); catalogued as rs769220327; ClinVar: pathogenic; called by muse, mutect2, varscan2
- VHL | c.236_241del p.R79_S80del | In Frame Del (DEL) | VAF 98/427 reads (23%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ABCA13 | c.11030C>G p.T3677R | Missense Mutation (SNP) | VAF 55/308 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs370836671; called by muse, mutect2, varscan2
- AOPEP | c.1565A>G p.Y522C | Missense Mutation (SNP) | VAF 71/300 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs1056026703; called by muse, mutect2, varscan2
- APC | c.7621A>G p.I2541V | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as rs587778033, CM080039, COSV57327926; ClinVar: benign / uncertain significance / likely benign; called by muse, mutect2, varscan2
- ASB9 | c.287A>G p.N96S | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs772925882; called by mutect2, varscan2
- C2CD3 | c.6871C>T p.R2291W | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1280936209; called by muse, mutect2, varscan2
- CSMD1 | c.3866G>T p.R1289L (on ENST00000520002; = p.R1288L on NM_033225.6) | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs780978438, COSV59300261, COSV59344665; called by muse, mutect2, varscan2
- LYPLAL1 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 18/368 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.166); catalogued as COSV65106608; called by muse, mutect2
- MYO5B | c.4875G>C p.E1625D | Missense Mutation (SNP) | VAF 48/258 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.071); catalogued as rs771235825; called by muse, varscan2
- OR11G2 | c.778G>A p.V260M | Missense Mutation (SNP) | VAF 80/252 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as rs769593612; called by muse, mutect2, varscan2
- ACTN1 | c.1336G>A p.A446T | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- ANKRD11 | c.3032A>C p.K1011T | Missense Mutation (SNP) | VAF 130/506 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- ASH1L | c.7559G>A p.R2520Q (on ENST00000368346 / NM_001366177.2; = p.R2515Q on NM_018489.3) | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- BSG | c.667G>A p.V223M | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ERAP2 | c.1038_1039dup p.T347Rfs*23 | Frame Shift Ins (INS) | VAF 83/339 reads (24%) | called by mutect2, pindel, varscan2
- GALNT14 | c.1469T>G p.L490R | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- HERC1 | c.9232G>C p.D3078H | Missense Mutation (SNP) | VAF 50/200 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KDM5B | c.1000T>A p.Y334N | Missense Mutation (SNP) | VAF 63/218 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KRT33B | c.1059C>G p.I353M | Missense Mutation (SNP) | VAF 47/340 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR10A6 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 36/243 reads (15%) | called by muse, mutect2, varscan2
- PBRM1 | c.3692-2A>C p.X1231_splice (on ENST00000296302 / NM_001366071.2; = p.X1206_splice on NM_018313.5) | Splice Site (SNP) | VAF 37/134 reads (28%) | called by muse, mutect2, varscan2
- PLCH2 | c.68T>G p.L23R | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- PLCH2 | c.2515G>T p.D839Y | Missense Mutation (SNP) | VAF 81/352 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- QSOX2 | c.337A>G p.S113G | Missense Mutation (SNP) | VAF 62/284 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- SLAMF6 | c.190T>C p.F64L | Missense Mutation (SNP) | VAF 82/418 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- SLC35G2 | c.386C>A p.S129Y | Missense Mutation (SNP) | VAF 47/283 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- SMG1 | c.2381T>C p.L794P | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- TEX51 | c.380G>A p.C127Y | Missense Mutation (SNP) | VAF 60/314 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- TJP2 | c.416_426del p.A139Dfs*5 | Frame Shift Del (DEL) | VAF 79/426 reads (19%) | called by mutect2, pindel, varscan2
- TMEM132A | c.2923C>T p.Q975* (on ENST00000453848 / NM_178031.3; = p.Q976* on NM_017870.4) | Nonsense Mutation (SNP) | VAF 19/104 reads (18%) | called by muse, mutect2, varscan2
- TSC2 | c.4492A>G p.S1498G | Missense Mutation (SNP) | VAF 39/283 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- UBR3 | c.583dup p.I195Nfs*6 | Frame Shift Ins (INS) | VAF 6/27 reads (22%) | called by mutect2, pindel, varscan2
- ZNF808 | c.2611G>A p.G871R | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ADAD1 | c.333G>A p.Q111= | Silent (SNP) | VAF 18/81 reads (22%) | called by mutect2, varscan2
- CCND3 | c.678A>G p.T226= | Silent (SNP) | VAF 33/228 reads (14%) | called by muse, mutect2, varscan2
- DHX37 | c.1426C>T p.L476= | Silent (SNP) | VAF 73/281 reads (26%) | called by muse, mutect2, varscan2
- DIP2A | c.3396C>T p.I1132= | Silent (SNP) | VAF 48/291 reads (16%) | called by muse, mutect2, varscan2
- EPG5 | c.291G>T p.T97= | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as rs376360251; called by muse, mutect2, varscan2
- HAGHL | c.433C>T p.L145= | Silent (SNP) | VAF 69/316 reads (22%) | called by muse, mutect2, varscan2
- KBTBD13 | c.699C>T p.P233= | Silent (SNP) | VAF 13/57 reads (23%) | called by muse, mutect2, varscan2
- LRP5 | c.2052G>T p.V684= | Silent (SNP) | VAF 41/185 reads (22%) | catalogued as rs771048928; called by muse, mutect2, varscan2
- MAN2A2 | c.2928C>T p.L976= | Silent (SNP) | VAF 36/173 reads (21%) | called by muse, mutect2, varscan2
- NAPRT | c.1113T>C p.S371= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV52786243; called by muse, mutect2
- OR4A47 | c.591G>C p.V197= | Silent (SNP) | VAF 30/137 reads (22%) | catalogued as COSV101487075; called by muse, mutect2, varscan2
- ORAI2 | c.276G>T p.P92= | Silent (SNP) | VAF 101/254 reads (40%) | catalogued as COSV62690482; called by muse, mutect2, varscan2
- RHBDF2 | c.1347G>T p.V449= | Silent (SNP) | VAF 52/186 reads (28%) | called by muse, mutect2, varscan2
- SYTL4 | c.741T>C p.N247= | Silent (SNP) | VAF 19/101 reads (19%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504139 T>C | 5'Flank (SNP) | VAF 17/70 reads (24%) | called by muse, mutect2, varscan2
- CBWD2 | c.-18G>A | 5'UTR (SNP) | VAF 35/143 reads (24%) | called by mutect2, varscan2
- CCDC189 | c.541-16C>T | Intron (SNP) | VAF 54/306 reads (18%) | catalogued as rs373928064; called by muse, mutect2, varscan2
- TAPBP | c.-9C>T | 5'UTR (SNP) | VAF 28/201 reads (14%) | catalogued as rs1171131413; called by muse, mutect2, varscan2
- TBCCD1 | chr3:186570144 C>T | 5'Flank (SNP) | VAF 13/98 reads (13%) | catalogued as rs1349957674; called by muse, mutect2, varscan2
- ZNF322P1 | n.292C>A | RNA (SNP) | VAF 50/274 reads (18%) | called by muse, mutect2, varscan2
